MMRF case MMRF_1978 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/59af5b70-9d0d-48c7-ab20-1bcba14eb03b

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 73 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 73.1 years (26,709 days); ISS stage: II; Days to last known disease status: 983 days (2.7 years); Days to last follow up: 983 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 281 days.
   Treatment given: Therapeutic agents: Melphalan + Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 263 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 5.51 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 54.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.932 mg/dL; Immunoglobulin G 65 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.21 g/L; Beta 2 Microglobulin 5.3 µg/mL; Lactate Dehydrogenase 5.48 µkat/L; Hemoglobin 5.64 mmol/L; Leukocytes 4.63 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 112 µmol/L; Blood Urea Nitrogen 11.8 mmol/L; Calcium 2.15 mmol/L; Albumin 33 g/L; Total Protein 11.9 g/dL; Glucose 5.56 mmol/L; C-Reactive Protein 0.2 mg/dL.
- Day 84: M Protein 2.57 g/dL; Lactate Dehydrogenase 7.85 µkat/L; Hemoglobin 6.88 mmol/L; Leukocytes 3.61 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 104 µmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 8.5 g/dL; Glucose 5.56 mmol/L.
- Day 190 (ECOG 0): M Protein 2.03 g/dL; Lactate Dehydrogenase 7.97 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 5.44 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 133 ×10⁹/L; Creatinine 96.4 µmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.8 g/dL; Glucose 5.61 mmol/L.
- Day 259 (ECOG 0): M Protein 2.03 g/dL; Beta 2 Microglobulin 4.7 µg/mL; Lactate Dehydrogenase 8.13 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.68 ×10⁹/L; Absolute Neutrophil 3.68 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 107 µmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 8 g/dL; Glucose 5.78 mmol/L.
- Day 329 (ECOG 0): M Protein 1.9 g/dL; Lactate Dehydrogenase 7.9 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.12 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 120 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 10.7 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.9 g/dL; Glucose 5.89 mmol/L.
- Day 469 (ECOG 0): M Protein 2.13 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 9.27 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 4 µg/mL; Lactate Dehydrogenase 7.17 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 126 µmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 8.2 g/dL; Glucose 5.56 mmol/L.
- Day 539 (ECOG 0): M Protein 1.71 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Lactate Dehydrogenase 7.32 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.24 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 114 µmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 8.2 g/dL; Glucose 5.61 mmol/L.
- Day 646 (ECOG 0): M Protein 2.86 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 25.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Lactate Dehydrogenase 7.12 µkat/L; Hemoglobin 6.26 mmol/L; Leukocytes 4.51 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 113 µmol/L; Calcium 2.23 mmol/L; Albumin 36 g/L; Total Protein 8.6 g/dL; Glucose 6.49 mmol/L.
- Day 716 (ECOG 0): M Protein 1.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.37 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.09 mg/dL; Lactate Dehydrogenase 7.8 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 5.01 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 180 ×10⁹/L; Creatinine 143 µmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 7.1 g/dL; Glucose 7.7 mmol/L.
- Day 814: M Protein 7.5 g/dL; Lactate Dehydrogenase 7.82 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 3.73 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 127 µmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.7 g/dL; Glucose 6.27 mmol/L.
- Day 884: Serum Free Immunoglobulin Light Chain, Kappa 4.52 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.58 mg/dL; Immunoglobulin A 1.6 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 6.4 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.81 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 142 ×10⁹/L; Creatinine 122 µmol/L; Calcium 2.28 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 6.11 mmol/L.
- Day 983 (ECOG 0): Lactate Dehydrogenase 5.62 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 2.75 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 106 µmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 5.83 mmol/L.

Other clinical attributes
- Day 0: Weight: 77 kg; Height: 168 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Prostate Cancer.

Biospecimens (3 samples)
- Sample MMRF_1978_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1978_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
- Sample MMRF_1978_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 646 days (1.8 years).
